Somatic mutation profile of tumor specimen TCGA-04-1638-01A (aliquot TCGA-04-1638-01A-01W-0639-09) from TCGA case TCGA-04-1638, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 57.5 years (20,987 days).
Specimen TCGA-04-1638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73d2294a-529f-4f74-a177-3a4b127cd309.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1638-11A (Solid Tissue Normal), aliquot TCGA-04-1638-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc0071b-2cc8-47f8-8a11-1844d122e4ed

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.3362T>C p.L1121P | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52183853; called by muse, mutect2, varscan2
- APOBEC3D | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV53325587, COSV99329194; called by muse, mutect2
- CFH | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 121/677 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV100661299, COSV62778634; called by muse, mutect2, varscan2
- COL11A2 | c.2646G>C p.Q882H (on ENST00000341947 / NM_080680.3; = p.Q775H on NM_080679.2) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100554533; called by muse, mutect2
- COL19A1 | c.1679A>T p.K560M | Missense Mutation (SNP) | VAF 110/218 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59585010; called by muse, mutect2, varscan2
- CRISP2 | c.337A>C p.S113R | Missense Mutation (SNP) | VAF 215/479 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV59256537; called by muse, mutect2, varscan2
- CXCL16 | c.517C>G p.H173D | Missense Mutation (SNP) | VAF 48/51 reads (94%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53412066; called by muse, mutect2, varscan2
- EIF4G2 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 278/529 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as COSV60598818; called by muse, mutect2, varscan2
- EMG1 | c.716A>C p.E239A | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV54643692; called by mutect2, varscan2
- FAT3 | c.8309del p.R2770Pfs*14 | Frame Shift Del (DEL) | VAF 19/37 reads (51%) | catalogued as COSV104401901, COSV53163429, COSV53181908; called by mutect2, pindel, varscan2
- FSD1 | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99697033; called by muse, mutect2
- HMCN1 | c.8137C>A p.Q2713K | Missense Mutation (SNP) | VAF 194/410 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1371222142, COSV54934168; called by muse, mutect2, varscan2
- IRS4 | c.2359G>A p.G787S | Missense Mutation (SNP) | VAF 111/125 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as rs1187459394, COSV64535622; called by muse, mutect2, varscan2
- KATNIP | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765836548, COSV55180497; called by muse, mutect2, varscan2
- KIF13B | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1306830181, COSV73054669; called by mutect2, varscan2
- KRT6A | c.1499C>A p.A500D | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV58107420; called by muse, mutect2, varscan2
- LOXL3 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV51212623; called by muse, mutect2, varscan2
- MAST4 | c.3707G>T p.G1236V (on ENST00000403625 / NM_001164664.2; = p.G1047V on NM_015183.3) | Missense Mutation (SNP) | VAF 89/172 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745678314, COSV55139160; called by mutect2, varscan2
- MGAT3 | c.828C>A p.H276Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57867925; called by muse, mutect2, varscan2
- NOTCH4 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as COSV100900388, COSV66683292; called by muse, mutect2, varscan2
- NUP98 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV61437600; called by muse, mutect2, varscan2
- OR4P4 | c.188A>T p.Y63F | Missense Mutation (SNP) | VAF 293/737 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100111861; called by muse, mutect2
- OR8K5 | c.831T>G p.F277L | Missense Mutation (SNP) | VAF 128/519 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.302); catalogued as COSV57890746; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs200556743, COSV53455192; called by muse, mutect2, varscan2
- PPP3R2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV62452672, COSV62455294; called by muse, mutect2
- PRXL2A | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 262/544 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs763602977, COSV64690536; called by muse, mutect2, varscan2
- PTOV1 | c.1076G>T p.C359F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55590210; called by muse, mutect2, varscan2
- RB1 | c.1684G>C p.A562P | Missense Mutation (SNP) | VAF 147/164 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57298250; called by muse, mutect2, varscan2
- RESF1 | c.504G>C p.M168I | Missense Mutation (SNP) | VAF 105/181 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV57025087; called by muse, mutect2, varscan2
- RSPH6A | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 58/63 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs186156470; called by muse, mutect2, varscan2
- SLC5A2 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs1567389730, COSV57894143; called by muse, mutect2, varscan2
- SPTA1 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV63758178; called by muse, mutect2, varscan2
- TLN2 | c.7000A>G p.K2334E | Missense Mutation (SNP) | VAF 101/188 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as COSV60894711; called by muse, mutect2, varscan2
- TMEFF1 | c.1007T>C p.I336T | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58495893, COSV58496769; called by muse, mutect2, varscan2
- TSC2 | c.778A>G p.M260V | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV54777517; called by muse, mutect2, varscan2
- USP13 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.006); catalogued as COSV55870080; called by muse, mutect2, varscan2
- VAT1L | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 95/208 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.055); catalogued as rs770757583, COSV56823913; called by muse, mutect2, varscan2
- ZFYVE1 | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as rs750032290, COSV59612746; called by muse, mutect2, varscan2
- ZNF516 | c.2075A>G p.E692G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV71587552; called by mutect2, varscan2
- ZSWIM1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.551); catalogued as COSV54850821; called by muse, mutect2, varscan2
- USH2A | c.12818_12819del p.Y4273Cfs*19 | Frame Shift Del (DEL) | VAF 201/660 reads (30%) | called by mutect2, pindel, varscan2
- A2M | c.1428C>T p.V476= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV59391622; called by mutect2, varscan2
- DSG4 | c.1803G>A p.A601= | Silent (SNP) | VAF 68/248 reads (27%) | catalogued as rs748792251, COSV57396653, COSV57398034; called by muse, mutect2, varscan2
- IQGAP3 | c.3948G>A p.G1316= | Silent (SNP) | VAF 327/541 reads (60%) | catalogued as COSV63254132; called by muse, varscan2
- KLB | c.2940A>G p.Q980= | Silent (SNP) | VAF 131/145 reads (90%) | catalogued as COSV57304713; called by muse, mutect2, varscan2
- MTIF2 | c.2022C>T p.T674= | Silent (SNP) | VAF 7/219 reads (3%) | catalogued as COSV99703277; called by muse, mutect2
- MYT1L | c.627C>T p.G209= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV67730479; called by mutect2, varscan2
- NEK9 | c.750G>A p.T250= | Silent (SNP) | VAF 6/200 reads (3%) | catalogued as rs1040448591, COSV99464532; called by muse, mutect2
- PRKCE | c.624C>T p.V208= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV60327774; called by muse, mutect2, varscan2
- PSME4 | c.3135T>C p.D1045= | Silent (SNP) | VAF 207/408 reads (51%) | catalogued as rs150490966; called by muse, mutect2, varscan2
- SIGLEC14 | c.339G>A p.T113= | Silent (SNP) | VAF 66/210 reads (31%) | catalogued as rs541001381, COSV55782987; called by muse, mutect2, varscan2
- UGT2B4 | c.534C>T p.Y178= | Silent (SNP) | VAF 52/1076 reads (5%) | catalogued as rs370531105; called by muse, mutect2
- MACF1 | c.16491+460G>C | Intron (SNP) | VAF 121/256 reads (47%) | catalogued as COSV57140239; called by muse, mutect2, varscan2
